Gene-level copy-number profile of tumor specimen TCGA-CN-6022-01A from TCGA case TCGA-CN-6022, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 49.2 years (17,971 days).
Specimen TCGA-CN-6022-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.195ff799-9af8-4a00-9106-b7d522fde56c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-6022-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/861d016c-ea94-46b0-a32e-41421f16d39e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 47; copy number 1: 2,579; copy number 2: 6,143; copy number 3: 32,357; copy number 4: 10,816; copy number 5: 7,720; copy number 6: 158.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-6022-01A-21D-1682-01): tumor purity 0.37, ploidy 3.13, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:241,532,134–241,677,376, 4 genes (within-gene range 0–3): KMO, OPN3, CHML, AL133390.1.
- chr9:21,304,326–22,455,740, 37 genes: IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr11:44,656,771–44,656,920, 1 gene: AC104010.1.
- chr11:135,061,781–135,075,908, 1 gene: LINC02684.
- chr13:33,158,587–33,164,409, 1 gene: STARD13-IT1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 196. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
